Somatic mutation profile of tumor specimen b87e7f88-a1f2-425a-8cff-8ae4b9 (aliquot b87e7f88-a1f2-425a-8cff-8ae4b9_D6_1) from CPTAC case 20BR008, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Intraductal papillary carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 71.9 years (26,249 days).
Specimen b87e7f88-a1f2-425a-8cff-8ae4b9: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eea819ca-a16e-4ece-8a90-08b99c87a006.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 393ad6ef-250a-493c-8c41-e47504 (Blood Derived Normal), aliquot 393ad6ef-250a-493c-8c41-e47504_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30713708-a5da-4e3f-9522-6402291a2863

The open-access MAF lists 110 somatic variants for this specimen: 72 protein-altering or splice-affecting, 24 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 24, Intron 7, Nonsense Mutation 5, 3'UTR 5, Splice Region 2, Frame Shift Del 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 334/900 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 45/126 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS17 | c.1750G>A p.G584S | Missense Mutation (SNP) | VAF 127/550 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as rs1434025252; called by muse, mutect2, varscan2
- AIM2 | c.519G>C p.K173N | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as rs572476207; called by muse, mutect2, varscan2
- AKAP10 | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 29/141 reads (21%) | catalogued as rs750037851; called by muse, mutect2, varscan2
- ANKLE1 | c.272T>C p.L91P (on ENST00000394458; = p.L37P on NM_152363.6) | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs945293318; called by muse, mutect2
- CCAR1 | c.1423C>T p.R475* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as COSV56271853; called by muse, mutect2, varscan2
- CLRN2 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 46/330 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs769214803; called by muse, mutect2, varscan2
- DNAH9 | c.2640G>T p.W880C | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52360093; called by muse, mutect2, varscan2
- DOP1A | c.7054G>A p.V2352M | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs756913283, COSV52706914; called by muse, mutect2, varscan2
- FETUB | c.224G>C p.R75P | Missense Mutation (SNP) | VAF 96/297 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV54006098; called by muse, mutect2, varscan2
- FSIP2 | c.15121C>G p.Q5041E | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.095); catalogued as rs1380774521, COSV58077376; called by muse, mutect2, varscan2
- KCNQ2 | c.1118+6G>A | Splice Region (SNP) | VAF 22/119 reads (18%) | catalogued as rs528957010; called by muse, mutect2, varscan2
- KDM8 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs764751277; called by muse, varscan2
- LRP1 | c.1797C>T p.D599= | Splice Region (SNP) | VAF 20/200 reads (10%) | catalogued as rs1290134523, COSV54506083; called by muse, mutect2
- MYBPC3 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 51/268 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as rs374255707, CM043538, COSV57028188; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO16 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1291880607, COSV51798056; called by muse, mutect2, varscan2
- NT5C1A | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as rs751819187, COSV52493348; called by muse, mutect2
- OR2B11 | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 44/516 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1352098491; called by muse, mutect2
- PHC3 | c.1288C>G p.L430V (on ENST00000494943 / NM_001308116.2; = p.L442V on NM_024947.4) | Missense Mutation (SNP) | VAF 96/524 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as COSV71949332; called by muse, mutect2, varscan2
- PRAMEF27 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 71/348 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1244279328; called by muse, varscan2
- PRRT4 | c.1996G>A p.A666T | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.037); catalogued as rs762909549, COSV71054887; called by muse, mutect2, varscan2
- RAD54L2 | c.3839C>T p.P1280L | Missense Mutation (SNP) | VAF 44/299 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as rs1441223626; called by muse, varscan2
- RIMS1 | c.3001G>T p.V1001F | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.209); catalogued as COSV99323277; called by muse, mutect2, varscan2
- SORCS2 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201499150, COSV61164376; called by muse, mutect2, varscan2
- SOX14 | c.498C>G p.Y166* | Nonsense Mutation (SNP) | VAF 30/312 reads (10%) | catalogued as rs753177973; called by muse, mutect2
- SRRT | c.1358C>T p.S453L | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV53816098; called by muse, mutect2, varscan2
- SULT4A1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753786397; called by muse, mutect2, varscan2
- TECTA | c.4168G>A p.A1390T | Missense Mutation (SNP) | VAF 43/318 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs1481202790, COSV50723773, COSV50838420; ClinVar: uncertain significance; called by mutect2, varscan2
- THRA | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 34/308 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); catalogued as COSV99225379; called by muse, mutect2
- TOGARAM1 | c.360G>C p.L120F | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV61889605; called by muse, mutect2
- TRPM4 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.055); catalogued as rs774915269; called by muse, mutect2, varscan2
- ZSWIM9 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.052); catalogued as COSV60888059; called by muse, mutect2, varscan2
- ADGRF1 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 24/281 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- ADGRV1 | c.12020G>C p.S4007T | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.014); called by muse, mutect2
- APAF1 | c.3574C>A p.L1192I (on ENST00000551964 / NM_181861.2; = p.L1138I on NM_001160.3) | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.59); called by muse, mutect2
- BAZ2A | c.2866G>A p.D956N | Missense Mutation (SNP) | VAF 45/350 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.027); called by muse, varscan2
- CEP192 | c.7321G>T p.A2441S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- CHST7 | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLPB | c.1195C>G p.H399D | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DCAF5 | c.1606A>T p.N536Y | Missense Mutation (SNP) | VAF 42/296 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- DFFB | c.316C>A p.L106M | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DHRS4L2 | c.682G>A p.D228N (on ENST00000559411; = p.D184N on NM_001193635.1) | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2
- DPYSL3 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 46/283 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- DST | c.1511A>C p.Q504P (on ENST00000361203 / NM_001374722.1; = p.Q178P on NM_001723.6) | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- FAAH2 | c.262_275+4dup | Nonsense Mutation (INS) | VAF 11/85 reads (13%) | called by mutect2, varscan2
- FAM166C | c.487T>C p.W163R | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FBXO46 | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 84/425 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- GDI1 | c.35C>A p.T12N | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- GRM8 | c.2263T>C p.Y755H | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HERC1 | c.9432T>G p.H3144Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- HERC1 | c.9431A>T p.H3144L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMCN1 | c.6637C>T p.L2213F | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HSPBP1 | c.930_945del p.C310Wfs*125 | Frame Shift Del (DEL) | VAF 37/247 reads (15%) | called by mutect2, pindel, varscan2
- IGSF1 | c.1694T>A p.I565K | Missense Mutation (SNP) | VAF 51/289 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MEFV | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.366); called by muse, mutect2
- MICAL2 | c.4274A>T p.K1425M | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- MYH6 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 78/766 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); called by muse, mutect2
- MYO3B | c.3778C>G p.R1260G | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- PCDHGA9 | c.1994C>G p.A665G | Missense Mutation (SNP) | VAF 43/496 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.327); called by muse, mutect2
- PRKCE | c.295A>T p.T99S | Missense Mutation (SNP) | VAF 62/253 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.042); called by mutect2, varscan2
- PTPRU | c.1195C>T p.Q399* | Nonsense Mutation (SNP) | VAF 20/180 reads (11%) | called by muse, mutect2, varscan2
- RCC1 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 29/279 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- RRP1 | c.67G>T p.V23L | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- SERPINA10 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 78/376 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- SFTPD | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- SPATA13 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- SYT5 | c.6C>A p.F2L | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated, low confidence (0.4); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- TAF1A | c.504T>G p.N168K | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- THBS4 | c.1384G>A p.G462R | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSHZ1 | c.1953C>A p.N651K (on ENST00000580243 / NM_001308210.2; = p.N606K on NM_005786.6) | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.86); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF473 | c.611A>C p.E204A | Missense Mutation (SNP) | VAF 50/280 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADGRE1 | c.1764C>T p.A588= | Silent (SNP) | VAF 21/143 reads (15%) | catalogued as rs767928378, COSV51675490; called by muse, mutect2, varscan2
- ANKEF1 | c.1299T>G p.L433= | Silent (SNP) | VAF 25/181 reads (14%) | called by muse, mutect2, varscan2
- CDK5RAP2 | c.115T>C p.L39= | Silent (SNP) | VAF 104/443 reads (23%) | called by muse, mutect2, varscan2
- COMMD4 | c.171C>T p.D57= | Silent (SNP) | VAF 102/368 reads (28%) | catalogued as rs200472461, COSV51191597; called by muse, mutect2, varscan2
- CSMD2 | c.648C>A p.P216= | Silent (SNP) | VAF 29/283 reads (10%) | catalogued as rs1400003903; called by muse, mutect2, varscan2
- DGKG | c.2052G>A p.R684= | Silent (SNP) | VAF 20/242 reads (8%) | catalogued as COSV99402462; called by muse, mutect2
- FAM8A1 | c.304C>A p.R102= | Silent (SNP) | VAF 6/93 reads (6%) | called by muse, mutect2
- FAP | c.2001C>A p.L667= | Silent (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- FHL1 | c.880C>A p.R294= | Silent (SNP) | VAF 27/161 reads (17%) | called by muse, mutect2, varscan2
- KIAA1671 | c.2388C>T p.A796= | Silent (SNP) | VAF 55/545 reads (10%) | called by muse, mutect2, varscan2
- KRTAP12-2 | c.159C>T p.A53= | Silent (SNP) | VAF 108/640 reads (17%) | catalogued as rs782366210; called by muse, varscan2
- OPLAH | c.3042C>T p.S1014= | Silent (SNP) | VAF 47/345 reads (14%) | catalogued as rs1431242492, COSV70679167; called by muse, mutect2, varscan2
- PDXDC1 | c.1650G>A p.K550= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV99816959; called by muse, mutect2, varscan2
- PLS3 | c.735A>G p.L245= | Silent (SNP) | VAF 33/141 reads (23%) | catalogued as rs1556639977; called by muse, mutect2, varscan2
- POLD1 | c.1294C>A p.R432= | Silent (SNP) | VAF 66/366 reads (18%) | catalogued as COSV70953953; called by muse, mutect2, varscan2
- PTPRO | c.2454C>T p.P818= | Silent (SNP) | VAF 40/339 reads (12%) | called by muse, mutect2, varscan2
- RBM19 | c.2016C>A p.L672= | Silent (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- RET | c.1233C>T p.S411= | Silent (SNP) | VAF 155/569 reads (27%) | catalogued as rs779374978, COSV100391927; called by muse, mutect2, varscan2
- SLC22A15 | c.75C>G p.A25= | Silent (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- TCN1 | c.822G>A p.T274= | Silent (SNP) | VAF 46/250 reads (18%) | catalogued as rs147802130; called by muse, mutect2, varscan2
- TICRR | c.2785C>T p.L929= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2
- UBTF | c.435T>A p.I145= | Silent (SNP) | VAF 17/115 reads (15%) | called by muse, mutect2, varscan2
- UNC13A | c.69C>T p.Y23= | Silent (SNP) | VAF 41/258 reads (16%) | catalogued as rs780941190; called by muse, mutect2, varscan2
- ZNF853 | c.1545C>T p.C515= | Silent (SNP) | VAF 37/204 reads (18%) | catalogued as rs986265815; called by muse, mutect2, varscan2
- ADGRL4 | c.22+24G>A | Intron (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- AL132655.6 | chr20:58840172 G>A | 5'Flank (SNP) | VAF 66/567 reads (12%) | catalogued as rs1380642653; called by muse, mutect2, varscan2
- ARHGAP25 | c.808-56del | Intron (DEL) | VAF 28/166 reads (17%) | called by mutect2, pindel, varscan2
- CHRNA4 | c.-41C>T | 5'UTR (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- DMTN | c.*827T>A | 3'UTR (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.13813-45C>A | Intron (SNP) | VAF 28/320 reads (9%) | called by muse, mutect2
- GADD45A | c.146+46C>T | Intron (SNP) | VAF 8/40 reads (20%) | catalogued as rs377316812; called by muse, mutect2, varscan2
- KCNC3 | c.*1403C>T | 3'UTR (SNP) | VAF 8/56 reads (14%) | catalogued as rs1405139110; called by muse, mutect2, varscan2
- P2RY12 | c.*8A>G | 3'UTR (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- PPDPFL | c.*618C>A | 3'UTR (SNP) | VAF 34/228 reads (15%) | called by muse, varscan2
- PPDPFL | c.*619A>G | 3'UTR (SNP) | VAF 39/234 reads (17%) | catalogued as rs542383719; called by muse, varscan2
- RAF1 | c.1417+25T>C | Intron (SNP) | VAF 22/85 reads (26%) | called by muse, mutect2, varscan2
- SIPA1 | c.680-15G>A | Intron (SNP) | VAF 11/102 reads (11%) | catalogued as COSV63138488, COSV63140678; called by muse, mutect2, varscan2
- TREML4 | c.506+2294T>A | Intron (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
